Somatic mutation profile of tumor specimen TCGA-DX-AB3C-01A (aliquot TCGA-DX-AB3C-01A-11D-A417-09) from TCGA case TCGA-DX-AB3C, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 27.5 years (10,034 days).
Specimen TCGA-DX-AB3C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c5f3b1a-db8c-49a4-bf63-c2b68afbaa4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB3C-10A (Blood Derived Normal), aliquot TCGA-DX-AB3C-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/557d9c04-d128-40ab-97f2-974c5ba28ca3

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTLN | c.2357A>T p.N786I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV99264367; called by muse, mutect2
- KIF27 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs777663766, COSV99927016; called by muse, mutect2, varscan2
- KRTAP27-1 | c.545A>C p.E182A | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.22); catalogued as COSV67001637; called by muse, mutect2
- LRBA | c.1336T>A p.S446T | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.983); catalogued as COSV100841663; called by muse, mutect2, varscan2
- NECTIN4 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.3); catalogued as COSV63512194; called by muse, mutect2, varscan2
- SCRT2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV99857175; called by muse, mutect2
- ABL1 | c.554_557del p.Y185Sfs*59 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | called by mutect2, pindel, varscan2
- AOX1 | c.63C>T p.V21= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs771741977, COSV101022211, COSV65980885; called by muse, mutect2, varscan2
- ZFP91 | c.1573C>A p.R525= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV60161880; called by muse, mutect2, varscan2
